Somatic mutation profile of tumor specimen TCGA-24-1850-01A (aliquot TCGA-24-1850-01A-01W-0639-09) from TCGA case TCGA-24-1850, project TCGA-OV (Ovarian Serous Cystadenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Serous cystadenocarcinoma, NOS; Tissue or organ of origin: Ovary; FIGO stage: Stage IIIC; Tumor grade: G3; Age at diagnosis: 72.2 years (26,369 days).
Specimen TCGA-24-1850-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) f8565ff9-5224-4e2d-9a25-4ee79d7d1b57.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-24-1850-10A (Blood Derived Normal), aliquot TCGA-24-1850-10A-01W-0639-09; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/ad6749b6-ca8f-4fd8-b4e2-f47c297f9ae4

The open-access MAF lists 88 somatic variants for this specimen: 72 protein-altering or splice-affecting, 13 silent, 3 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 54, Silent 13, Frame Shift Del 6, Nonsense Mutation 5, Intron 3, Frame Shift Ins 3, Splice Site 2, In Frame Del 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- GCK | c.127C>T p.R43C | Missense Mutation (SNP) | VAF 11/48 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as rs1486280029, CM074225, CM096808, CM096809, COSV61753220, COSV61754992; ClinVar: pathogenic; called by muse, mutect2, varscan2
- TP53 | c.438G>A p.W146* | Nonsense Mutation (SNP) | VAF 57/80 reads (71%) | hotspot (GDC flag); catalogued as rs1131691026, CM101750, COSV52661500, COSV52987374, COSV53571745; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADARB2 | c.2075C>T p.T692M | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.09); PolyPhen benign (0.148); catalogued as rs367615505; called by muse, mutect2, varscan2
- ADGRL2 | c.196C>G p.R66G | Missense Mutation (SNP) | VAF 24/54 reads (44%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54663886; called by muse, mutect2, varscan2
- ADGRV1 | c.4602C>G p.D1534E | Missense Mutation (SNP) | VAF 21/79 reads (27%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV67983583; called by muse, mutect2, varscan2
- C2orf78 | c.1391A>G p.D464G | Missense Mutation (SNP) | VAF 15/101 reads (15%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.999); catalogued as COSV68517301; called by muse, mutect2, varscan2
- CACNA1S | c.3685C>G p.R1229G | Missense Mutation (SNP) | VAF 15/45 reads (33%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.745); catalogued as rs781070076, COSV62938772; called by muse, mutect2, varscan2
- CACNG4 | c.916T>A p.F306I | Missense Mutation (SNP) | VAF 103/192 reads (54%) | SIFT tolerated (0.19); PolyPhen benign (0.053); catalogued as COSV50924722; called by muse, mutect2, varscan2
- CFAP36 | c.226G>A p.E76K | Missense Mutation (SNP) | VAF 8/45 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.983); catalogued as COSV59117413; called by muse, mutect2, varscan2
- CHEK2 | c.134C>T p.T45M | Missense Mutation (SNP) | VAF 10/62 reads (16%) | SIFT deleterious, low confidence (0.01); PolyPhen possibly damaging (0.809); catalogued as rs558321010, COSV60419096; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- CLCC1 | c.286G>A p.V96I | Missense Mutation (SNP) | VAF 13/26 reads (50%) | SIFT tolerated (0.55); PolyPhen benign (0.161); catalogued as COSV56763074; called by muse, mutect2, varscan2
- COL5A3 | c.2329C>G p.P777A | Missense Mutation (SNP) | VAF 6/28 reads (21%) | SIFT tolerated (0.15); PolyPhen benign (0.007); catalogued as rs754988644, COSV53407546, COSV53409885; called by muse, mutect2
- DNAH2 | c.6742-2A>C p.X2248_splice | Splice Site (SNP) | VAF 11/78 reads (14%) | catalogued as COSV66718685; called by muse, mutect2, varscan2
- DYRK2 | c.1156C>T p.R386C (on ENST00000344096 / NM_006482.3; = p.R313C on NM_003583.4) | Missense Mutation (SNP) | VAF 50/137 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV59845925; called by muse, mutect2, varscan2
- EGFR | c.783G>T p.K261N | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.984); catalogued as COSV51792742; called by muse, mutect2, varscan2
- ERMARD | c.202G>C p.V68L | Missense Mutation (SNP) | VAF 25/70 reads (36%) | SIFT deleterious (0.02); PolyPhen benign (0.365); catalogued as COSV100824886, COSV64650157; called by muse, mutect2, varscan2
- ETFDH | c.929A>C p.Y310S | Missense Mutation (SNP) | VAF 29/92 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV57014701; called by muse, mutect2, varscan2
- FAM217A | c.893A>T p.H298L | Missense Mutation (SNP) | VAF 30/99 reads (30%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as rs775948565, COSV51159714; called by muse, mutect2, varscan2
- FLG | c.4775C>A p.S1592Y | Missense Mutation (SNP) | VAF 35/196 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.017); catalogued as COSV64240591; called by muse, mutect2, varscan2
- FOCAD | c.4908C>T p.G1636= | Splice Region (SNP) | VAF 6/45 reads (13%) | catalogued as rs781242155, COSV58097403; called by muse, mutect2, varscan2
- FOLH1 | c.1580G>A p.R527Q | Missense Mutation (SNP) | VAF 39/134 reads (29%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.544); catalogued as rs1262353651, COSV57048182; called by muse, mutect2, varscan2
- GINM1 | c.376A>T p.S126C | Missense Mutation (SNP) | VAF 14/72 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.794); catalogued as COSV66389686; called by muse, mutect2, varscan2
- GPT2 | c.1259C>T p.T420M | Missense Mutation (SNP) | VAF 4/40 reads (10%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.921); catalogued as rs766358249, COSV100412923, COSV60839604; called by mutect2, varscan2
- HRNR | c.2797G>C p.G933R | Missense Mutation (SNP) | VAF 20/93 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.062); catalogued as rs769111271, COSV64257030; called by muse, mutect2, varscan2
- IFNAR1 | c.1564G>A p.E522K | Missense Mutation (SNP) | VAF 25/73 reads (34%) | SIFT tolerated (0.19); PolyPhen benign (0.042); catalogued as COSV54251662, COSV54254370; called by muse, mutect2, varscan2
- ISM1 | c.1017C>G p.D339E | Missense Mutation (SNP) | VAF 3/24 reads (13%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99339869; called by muse, mutect2
- ITGAE | c.1700G>T p.S567I | Missense Mutation (SNP) | VAF 42/144 reads (29%) | SIFT tolerated (0.08); PolyPhen benign (0.36); catalogued as COSV53992961; called by muse, mutect2, varscan2
- JCAD | c.715G>A p.E239K | Missense Mutation (SNP) | VAF 38/167 reads (23%) | SIFT tolerated (0.1); PolyPhen benign (0.243); catalogued as rs750798343, COSV64759194; called by muse, mutect2, varscan2
- KCNH5 | c.2254G>A p.V752M | Missense Mutation (SNP) | VAF 36/72 reads (50%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.506); catalogued as rs887460066, COSV59757888; called by muse, mutect2, varscan2
- KNCN | c.25G>C p.D9H | Missense Mutation (SNP) | VAF 10/24 reads (42%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.998); catalogued as COSV99606294; called by muse, mutect2
- LRP1 | c.8632T>C p.C2878R | Missense Mutation (SNP) | VAF 9/27 reads (33%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.998); catalogued as COSV99675834; called by muse, mutect2, varscan2
- LYG1 | c.490G>C p.G164R | Missense Mutation (SNP) | VAF 26/128 reads (20%) | SIFT deleterious (0); PolyPhen possibly damaging (0.824); catalogued as COSV57915388; called by muse, mutect2, varscan2
- MARCHF10 | c.851G>T p.S284I | Missense Mutation (SNP) | VAF 32/660 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.057); catalogued as COSV100248180, COSV60886835; called by muse, mutect2
- MARCHF11 | c.1031T>C p.L344S | Missense Mutation (SNP) | VAF 117/227 reads (52%) | SIFT tolerated (0.15); PolyPhen benign (0.038); catalogued as COSV60127833; called by muse, mutect2, varscan2
- MAT2A | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.518); catalogued as COSV52087974; called by muse, mutect2, varscan2
- MRPL30 | c.188C>A p.P63H | Missense Mutation (SNP) | VAF 27/112 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV57666800; called by muse, mutect2, varscan2
- MYOCD | c.1862C>G p.T621S | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs773761570, COSV58502175; called by muse, varscan2
- MYOM2 | c.938G>A p.R313H | Missense Mutation (SNP) | VAF 10/14 reads (71%) | SIFT deleterious (0.01); PolyPhen benign (0.031); catalogued as rs759987270, COSV50708811, COSV50721592; called by muse, mutect2
- NFATC2 | c.1535C>T p.T512I | Missense Mutation (SNP) | VAF 18/110 reads (16%) | SIFT tolerated (1); PolyPhen benign (0.196); catalogued as rs375019669, COSV65355142; called by muse, mutect2
- NUP214 | c.6164G>T p.G2055V | Missense Mutation (SNP) | VAF 4/36 reads (11%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.88); catalogued as COSV100845283; called by muse, mutect2
- OR10Q1 | c.838G>A p.A280T | Missense Mutation (SNP) | VAF 73/184 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.943); catalogued as rs778216887, COSV57469754; called by muse, mutect2, varscan2
- OR2T2 | c.912A>T p.K304N | Missense Mutation (SNP) | VAF 13/83 reads (16%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.526); catalogued as COSV61617954; called by muse, mutect2, varscan2
- OR4K14 | c.501G>C p.L167F | Missense Mutation (SNP) | VAF 21/153 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV59292634, COSV59292640; called by muse, mutect2, varscan2
- PALM2AKAP2 | c.208C>T p.R70W (on ENST00000374531 / NM_001037293.2; = p.R68W on NM_007203.5) | Missense Mutation (SNP) | VAF 34/57 reads (60%) | SIFT deleterious (0); PolyPhen possibly damaging (0.877); catalogued as rs752297384, COSV57118999; called by muse, mutect2, varscan2
- PLXNC1 | c.2072C>T p.S691L | Missense Mutation (SNP) | VAF 19/69 reads (28%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.587); catalogued as rs1316148805, COSV51573909; called by muse, mutect2, varscan2
- PNPLA6 | c.2458A>G p.I820V (on ENST00000414982 / NM_001166111.2; = p.I772V on NM_006702.5) | Missense Mutation (SNP) | VAF 10/153 reads (7%) | SIFT tolerated (0.47); PolyPhen benign (0); catalogued as COSV99653711; called by muse, mutect2
- PPFIA1 | c.583G>A p.E195K | Missense Mutation (SNP) | VAF 8/103 reads (8%) | SIFT deleterious (0); PolyPhen benign (0.081); catalogued as COSV99557436; called by muse, mutect2
- PTPRK | c.2051C>G p.P684R | Missense Mutation (SNP) | VAF 15/70 reads (21%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.995); catalogued as COSV63895721; called by muse, mutect2, varscan2
- PZP | c.3200C>A p.A1067E | Missense Mutation (SNP) | VAF 68/152 reads (45%) | SIFT tolerated (0.48); PolyPhen benign (0.101); catalogued as COSV54358632; called by muse, varscan2
- RAB3D | c.281del p.G94Efs*79 | Frame Shift Del (DEL) | VAF 16/111 reads (14%) | catalogued as COSV99032924; called by mutect2, pindel, varscan2
- RAE1 | c.476G>T p.R159L | Missense Mutation (SNP) | VAF 26/193 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV64798104; called by muse, mutect2, varscan2
- ROBO1 | c.4258C>T p.R1420* | Nonsense Mutation (SNP) | VAF 9/23 reads (39%) | catalogued as rs751773740, COSV71393603; called by muse, mutect2, varscan2
- SAMD9 | c.3554C>G p.S1185* | Nonsense Mutation (SNP) | VAF 83/309 reads (27%) | catalogued as COSV66074598; called by muse, mutect2, varscan2
- SAMD9L | c.1442G>C p.W481S | Missense Mutation (SNP) | VAF 67/240 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV59080895, COSV59080935; called by muse, mutect2, varscan2
- SLC7A14 | c.748G>A p.G250S | Missense Mutation (SNP) | VAF 18/132 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs763399787, COSV51577661; called by mutect2, varscan2
- SLC8A1 | c.444G>T p.E148D | Missense Mutation (SNP) | VAF 20/162 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV60478133; called by muse, mutect2, varscan2
- STAMBP | c.203+1G>T p.X68_splice | Splice Site (SNP) | VAF 16/115 reads (14%) | catalogued as COSV59896869; called by muse, mutect2, varscan2
- TASOR2 | c.6510C>G p.H2170Q | Missense Mutation (SNP) | VAF 9/109 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.436); catalogued as COSV100050499; called by muse, mutect2
- USF3 | c.5972G>A p.R1991H | Missense Mutation (SNP) | VAF 15/49 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs776587053, COSV57071878; called by muse, mutect2, varscan2
- ZKSCAN4 | c.931C>T p.Q311* | Nonsense Mutation (SNP) | VAF 25/101 reads (25%) | catalogued as COSV66023407; called by muse, mutect2, varscan2
- ZNF862 | c.2334C>G p.I778M | Missense Mutation (SNP) | VAF 4/8 reads (50%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as COSV56223626; called by muse, mutect2, varscan2
- ZSCAN1 | c.658C>A p.L220I | Missense Mutation (SNP) | VAF 8/57 reads (14%) | SIFT tolerated (0.34); PolyPhen benign (0.001); catalogued as rs1399001562, COSV56603728; called by muse, mutect2, varscan2
- ABT1 | c.683_691del p.P228_G230del | In Frame Del (DEL) | VAF 9/34 reads (26%) | called by mutect2, pindel, varscan2
- B3GNT3 | c.614_620del p.F205Sfs*32 | Frame Shift Del (DEL) | VAF 6/54 reads (11%) | called by mutect2, pindel
- DUSP14 | c.362_371dup p.Y125Vfs*51 | Frame Shift Ins (INS) | VAF 10/49 reads (20%) | called by mutect2, varscan2
- FKBP10 | c.523_530dup p.R178Tfs*36 | Frame Shift Ins (INS) | VAF 10/28 reads (36%) | called by mutect2, varscan2
- GLRA1 | c.588del p.F196Lfs*11 | Frame Shift Del (DEL) | VAF 22/66 reads (33%) | called by mutect2, pindel
- MCMBP | c.1638_1654dup p.R552Pfs*3 | Nonsense Mutation (INS) | VAF 24/82 reads (29%) | called by mutect2, varscan2
- MRPS35 | c.702+1del | Frame Shift Del (DEL) | VAF 13/65 reads (20%) | called by mutect2, pindel, varscan2
- MTG2 | c.133_145del p.S45Rfs*20 | Frame Shift Del (DEL) | VAF 9/46 reads (20%) | called by mutect2, pindel
- TLE1 | c.1944_1947del p.R649Sfs*37 | Frame Shift Del (DEL) | VAF 6/26 reads (23%) | called by mutect2, varscan2
- ZNF473 | c.2134dup p.R712Pfs*8 | Frame Shift Ins (INS) | VAF 31/162 reads (19%) | called by mutect2, pindel, varscan2
- CADM4 | c.837G>A p.P279= | Silent (SNP) | VAF 5/19 reads (26%) | catalogued as rs145789919, COSV55928595; called by muse, mutect2, varscan2
- EPS15L1 | c.84G>A p.P28= | Silent (SNP) | VAF 22/169 reads (13%) | catalogued as rs778115246, COSV50168239; called by muse, mutect2, varscan2
- IMPDH1 | c.1179G>A p.T393= (on ENST00000470772 / NM_001142573.2; = p.T479= on NM_000883.4) | Silent (SNP) | VAF 7/35 reads (20%) | catalogued as rs762575513, COSV58315758; called by muse, mutect2, varscan2
- MED22 | c.363C>T p.D121= | Silent (SNP) | VAF 28/59 reads (47%) | catalogued as rs146119308; called by muse, mutect2, varscan2
- MYH7 | c.711G>A p.R237= | Silent (SNP) | VAF 100/277 reads (36%) | catalogued as COSV62518450; called by muse, mutect2, varscan2
- NBAS | c.2307A>C p.P769= | Silent (SNP) | VAF 20/175 reads (11%) | catalogued as COSV55718951; called by muse, mutect2, varscan2
- NNT | c.2412C>T p.G804= | Silent (SNP) | VAF 15/91 reads (16%) | catalogued as COSV52924327; called by muse, mutect2, varscan2
- NR2C1 | c.870A>G p.Q290= | Silent (SNP) | VAF 16/45 reads (36%) | catalogued as COSV58009455; called by muse, mutect2, varscan2
- NUP155 | c.1938C>T p.A646= (on ENST00000231498 / NM_153485.3; = p.A587= on NM_004298.4) | Silent (SNP) | VAF 20/117 reads (17%) | catalogued as COSV51529161; called by muse, mutect2, varscan2
- OR52K2 | c.894C>T p.T298= | Silent (SNP) | VAF 145/604 reads (24%) | catalogued as COSV57834991; called by muse, mutect2, varscan2
- RBM26 | c.2049A>C p.A683= (on ENST00000438737 / NM_001366735.2; = p.A685= on NM_001286631.1) | Silent (SNP) | VAF 3/12 reads (25%) | catalogued as COSV57393559; called by muse, mutect2, varscan2
- RHNO1 | c.429G>A p.Q143= | Silent (SNP) | VAF 33/173 reads (19%) | catalogued as rs1179077997, COSV63485282; called by muse, mutect2, varscan2
- ZFP36L1 | c.30C>T p.I10= | Silent (SNP) | VAF 27/142 reads (19%) | catalogued as rs1421608448, COSV60545088, COSV60547534; called by muse, mutect2, varscan2
- ACP1 | c.231+77C>T | Intron (SNP) | VAF 11/58 reads (19%) | catalogued as rs1253153939, COSV55242975; called by muse, mutect2, varscan2
- C22orf15 | c.251-58C>T | Intron (SNP) | VAF 12/25 reads (48%) | catalogued as COSV59417883; called by muse, mutect2, varscan2
- KAT6A | c.1483-1833C>T | Intron (SNP) | VAF 61/138 reads (44%) | catalogued as rs771160951, COSV55905295; called by muse, mutect2, varscan2
